Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OH, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OH-01A (Primary Tumor).

[page 1 of 3]
ICB-0-3
adenocarcinoma, nos 8140/3
Site: esophagus, distal third C15.5
hw
10/9/12

Esophageal adenocarcinoma. Operative Procedure/Tissue Submitted: Transhiatal
esophagectomy. Davinci-distal esophagus, proximal stomach (tissue
procurement).

PROCEDURE: SPGD

1. "Distal esophagus, proximal stomach." Received in formalin in a large
container is a 19.7 cm segment of distal esophagus and proximal stomach. The
proximal and distal margins are stapled. The portion of esophagus is 11.5 cm

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: M

and the gastric portion is 8 cm. The adventitia is unremarkable, as well as the gastric serosa. There is a small amount of adherent perigastric fat that is focally hemorrhagic. The adventitia is inked blue and the gastric serosa is inked green. Arising in the GE junction is a 2.2 x 1.7 cm, centrally ulcerated mass that comes to within 6.2 cm of the gastric margin. Most of the mass involves the gastric mucosa, with a 0.8 cm portion involving the esophageal mucosa. The cut surface through the mass shows its maximum thickness of 0.7 cm, penetrating into the submucosa but not involving the muscular wall or adventitia. Lymph node candidates from perigastric fat are retrieved up to 0.8 cm in greatest dimension.

1A-E. Mass at GE junction.

1F. Nine whole lymph node candidates. Fat retained.

2. "Cervical esophageal margin." Received in formalin in a small container is a 1.1 cm segment of esophageal tissue that is stapled at one margin and open at the opposing margin. The adventitia is unremarkable, and the mucosa is unremarkable. There is submucosal hemorrhage in the short segment.

2A. Cervical esophageal margin.

PROCEDURE: SPMI

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA,
CARCINOMA (RESECTION SPECIMENS):

=====

LOCATION: Gastroesophageal junction, straddling the junction
SIZE: 2.2 cm
TYPE OF CARCINOMA: Adenocarcinoma not arising in Barrett's mucosa
DEPTH OF INVASION: Submucosa
HAS IT BEEN TREATED PREOPERATIVELY WITH CHEMO/RADIATION THERAPY? No
NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/9

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

pT1b N0

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 5
SEX: M

PROCEDURE: SPDX

1&2. Esophagus, resection: Invasive adenocarcinoma (2.2 cm) arising at the gastroesophageal junction and extending into the submucosa. Lymphovascular invasion present. Margins free. Nine lymph nodes, negative for malignancy (0/9). Please see template above.

the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

H&A Discrepancy		
Primary Malignancy History		
Discrepancy Primary Noted		
Comments:	QUALIFIED / QUALIFIED Date Reviewed: 10/9/12	

Source: NCI Genomic Data Commons file 62cf013c-c0ce-4460-b1a7-f0d363c4b0cf (TCGA-L5-A4OH.9BA4F920-FDFB-4375-ABB9-F76D5317D941.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).